Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5121, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5121-01A (Primary Tumor).

SIS: Right renal mass.

FINAL DIAGNOSIS:

KIDNEY, RIGHT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CLEAR CELL TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 2 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 4.5 cm.
- D. THE NEOPLASM IS CONFINED TO THE KIDNEY WITHOUT EXTRACAPSULAR EXTENSION.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. TNM STAGE: pT1b NX MX.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:	Radical nephrectomy
LATERALITY:	Right
TUMOR SITE:	Upper pole
FOCALITY:	Unifocal
TUMOR SIZE:	Greatest dimension: 4.5 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor limited to kidney
HISTOLOGIC TYPE:	Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G2
PATHOLOGIC STAGING (pTNM):	pT1b
	pNX
	Number of regional lymph nodes examined: 0
MARGINS:	pMX
ADRENAL GLAND:	Margins uninvolved by invasive carcinoma
LYMPH-VASCULAR INVASION (LVI):	Not present
KIDNEY-RESIDUAL TUMOR (R):	Absent/not identified
	R0

Source: NCI Genomic Data Commons file 089fab33-0d28-40ea-82b6-7fecabcbd8e5 (TCGA-B0-5121.32113A43-9B41-4439-A111-9DF446BDBAF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).